HCMI case HCM-BROD-0417-C71 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Gliomas; Primary site: Brain. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/0798bf7a-53f3-4d88-a863-b4fc186bb5b6

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1962; Vital status: Dead; Days to death: 513 days (1.4 years); Cause of death: Cancer Related.

Diagnoses (1)
1. Glioblastoma: ICD-O-3 morphology code: 9440/3; ICD-10 code: C71.9; Tissue or organ of origin: Brain, NOS; Site of resection or biopsy: Brain, NOS; Classification of tumor: primary; Age at diagnosis: 50.0 years (18,275 days); WHO CNS grade: Grade IV; Metastasis at diagnosis: No Metastasis; Prior malignancy: no; Prior treatment: No.
   Pathology details: Necrosis present: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis; Days to treatment start: 2 days.
   Treatment given: Treatment type: Radiation Therapy, NOS; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 31 days; Days to treatment end: 170 days.
   Treatment given: Treatment type: Targeted Molecular Therapy; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 31 days; Days to treatment end: 170 days.
   Treatment given: Treatment type: Targeted Molecular Therapy; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 207 days; Days to treatment end: 287 days.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Lomustine; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 292 days; Days to treatment end: 403 days (1.1 years).
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Bevacizumab; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 417 days (1.1 years); Days to treatment end: 501 days (1.4 years).
   Treatment given: Treatment type: Immunotherapy (Including Vaccines); Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 417 days (1.1 years); Days to treatment end: 473 days (1.3 years).
   Recorded as not given: neoadjuvant treatment (type not reported).

Follow-up (3 entries)
- Days to follow up: 98 days; Karnofsky performance status: 90.
- Days to follow up: 501 days (1.4 years); Disease response: Progressive Disease; Progression or recurrence: Yes.
- Follow-up contact recording only the day: day 0.

Molecular and laboratory tests
- IDH1 (IHC): Negative; Amino-acid change: R132H.
- IDH1 / IDH2 (Targeted Sequencing): Negative.
- MGMT partial methylation: Positive.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 105 kg; Height: 171 cm; BMI: 35.9.

Family history
- Relationship type: First Degree Relative, NOS.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample HCM-BROD-0417-C71-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
  Slide HCM-BROD-0417-C71-01A-01-S1-HE: Section location: Top; Percent tumor cells: 67; Percent tumor nuclei: 88; Percent normal cells: 9; Percent necrosis: 20; Percent stromal cells: 4; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
  Slide HCM-BROD-0417-C71-01A-01-S2-HE: Section location: Bottom; Percent tumor cells: 59; Percent tumor nuclei: 84; Percent normal cells: 11; Percent necrosis: 17; Percent stromal cells: 13; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample HCM-BROD-0417-C71-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Whole Blood; Preservation method: Frozen.
- Sample HCM-BROD-0417-C71-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Neurosphere; Preservation method: Frozen; Passage count: 10.
